Somatic mutation profile of tumor specimen ALCH-AE5D-TTP1-A (aliquot ALCH-AE5D-TTP1-A-1-0-D-A604-36) from ALCHEMIST case ALCH-AE5D, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 62.1 years (22,665 days).
Specimen ALCH-AE5D-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1e7eb55f-240c-41d7-af4f-ab93b9cd3bce.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AE5D-NB1-A (Blood Derived Normal), aliquot ALCH-AE5D-NB1-A-1-0-D-A604-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3c8deb43-533e-4e13-94ac-771e198198ef

The open-access MAF lists 673 somatic variants for this specimen: 442 protein-altering or splice-affecting, 141 silent, 90 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 367, Silent 141, Nonsense Mutation 47, Intron 42, RNA 15, 3'UTR 14, 5'Flank 9, Splice Region 8, 5'UTR 8, Frame Shift Del 7, Splice Site 6, Frame Shift Ins 6.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCNQ2 | c.544G>A p.V182M | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1085307920; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 411/960 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.488A>G p.Y163C | Missense Mutation (SNP) | VAF 34/556 reads (6%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148924904, CM942135, COSV52663142, COSV52676381; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- TP53 | c.375G>T p.T125= | Splice Region (SNP) | VAF 22/223 reads (10%) | catalogued as rs55863639, CS004351, CS011573, CS971913, COSV52665709, COSV52718605, COSV52726641, COSV53120615; ClinVar: not provided / likely pathogenic; called by muse, mutect2
- A1BG | c.1349G>T p.G450V | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.044); catalogued as COSV54052404; called by muse, mutect2, varscan2
- ABCC5 | c.2315A>G p.N772S | Missense Mutation (SNP) | VAF 14/326 reads (4%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs1236694777; called by muse, mutect2
- ACSM2A | c.49C>A p.Q17K | Missense Mutation (SNP) | VAF 25/260 reads (10%) | SIFT tolerated (0.71); PolyPhen benign (0.025); catalogued as COSV99525785; called by muse, mutect2, varscan2
- ADCY5 | c.2384C>T p.T795I | Missense Mutation (SNP) | VAF 38/284 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as COSV59203278; called by muse, mutect2, varscan2
- AFF3 | c.1886C>A p.P629H | Missense Mutation (SNP) | VAF 28/306 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57863761; called by muse, mutect2
- AHNAK2 | c.6872C>T p.P2291L | Missense Mutation (SNP) | VAF 144/1506 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.074); catalogued as rs1390338658, COSV60908084; called by muse, mutect2
- ANO4 | c.4G>T p.E2* | Nonsense Mutation (SNP) | VAF 46/246 reads (19%) | catalogued as COSV100152061; called by muse, mutect2, varscan2
- APOA1 | c.355G>T p.A119S | Missense Mutation (SNP) | VAF 120/1049 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV99369349; called by muse, mutect2, varscan2
- ARHGEF11 | c.1797G>T p.E599D | Missense Mutation (SNP) | VAF 18/178 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.009); catalogued as COSV59355503; called by muse, mutect2, varscan2
- ATG2B | c.3190G>A p.A1064T | Missense Mutation (SNP) | VAF 15/152 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.073); catalogued as rs1160959780; called by muse, mutect2, varscan2
- ATP6V0A4 | c.865G>T p.A289S | Missense Mutation (SNP) | VAF 126/681 reads (19%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.598); catalogued as COSV100022593, COSV59477638; called by muse, mutect2, varscan2
- BCHE | c.964G>T p.V322L | Missense Mutation (SNP) | VAF 32/174 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.27); catalogued as CM080101, COSV52263033; called by muse, mutect2, varscan2
- BCORL1 | c.4697-1G>A p.X1566_splice | Splice Site (SNP) | VAF 12/44 reads (27%) | catalogued as COSV54405049; called by muse, mutect2, varscan2
- BRMS1L | c.694G>T p.A232S | Missense Mutation (SNP) | VAF 28/295 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.045); catalogued as COSV53762981; called by muse, mutect2
- C11orf16 | c.148G>T p.G50W | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as COSV58167663; called by muse, mutect2, varscan2
- C6orf58 | c.806G>A p.R269Q | Missense Mutation (SNP) | VAF 68/586 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.718); catalogued as rs749468767, COSV61665958, COSV61667200; called by muse, mutect2, varscan2
- C8orf34 | c.496G>T p.D166Y | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV61382330; called by muse, mutect2
- CBFA2T3 | c.80C>A p.P27H | Missense Mutation (SNP) | VAF 55/326 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.174); catalogued as rs139809332; called by muse, mutect2, varscan2
- CCBE1 | c.774C>A p.P258= | Splice Region (SNP) | VAF 38/411 reads (9%) | catalogued as rs776263282, COSV67950344; called by muse, mutect2
- CCDC168 | c.14803G>C p.E4935Q | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as COSV59421526; called by muse, mutect2, varscan2
- CDCA7L | c.1154G>C p.R385P | Missense Mutation (SNP) | VAF 20/176 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60983497; called by muse, mutect2
- CDH12 | c.2152C>A p.H718N | Missense Mutation (SNP) | VAF 58/546 reads (11%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV66395062; called by muse, mutect2, varscan2
- CEP170B | c.3752G>T p.R1251L (on ENST00000453495; = p.R1180L on NM_015005.3) | Missense Mutation (SNP) | VAF 69/279 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.793); catalogued as rs140736162; called by muse, mutect2, varscan2
- CFAP44 | c.611G>C p.G204A | Missense Mutation (SNP) | VAF 25/224 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99870168; called by muse, mutect2, varscan2
- CFAP54 | c.7267G>T p.E2423* | Nonsense Mutation (SNP) | VAF 107/569 reads (19%) | catalogued as rs1251317768; called by muse, mutect2, varscan2
- COL22A1 | c.130G>T p.D44Y | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57341433; called by muse, mutect2, varscan2
- CPED1 | c.508G>T p.E170* | Nonsense Mutation (SNP) | VAF 42/407 reads (10%) | catalogued as rs1410851314; called by muse, mutect2
- CPS1 | c.602T>A p.I201N | Missense Mutation (SNP) | VAF 39/571 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.362); catalogued as COSV51817268; called by muse, mutect2
- CRISP3 | c.545G>T p.G182V (on ENST00000371159 / NM_001368123.1; = p.G164V on NM_006061.4) | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53823805, COSV99539266; called by muse, mutect2
- DHX9 | c.3620G>T p.R1207L | Missense Mutation (SNP) | VAF 62/848 reads (7%) | SIFT tolerated (0.76); PolyPhen benign (0.007); catalogued as COSV100841221, COSV62360477; called by muse, mutect2
- DIO3 | c.607C>G p.P203A | Missense Mutation (SNP) | VAF 66/1006 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.247); catalogued as COSV63773312; called by muse, mutect2
- DOCK9 | c.3668A>G p.K1223R (on ENST00000376460 / NM_001366676.2; = p.K1224R on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/217 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as rs1480578973; called by muse, mutect2
- DSCAM | c.1591C>T p.P531S | Missense Mutation (SNP) | VAF 36/409 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV68020364; called by muse, mutect2
- DYNC1LI1 | c.1534A>T p.T512S | Missense Mutation (SNP) | VAF 33/223 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.341); catalogued as COSV56127549; called by muse, mutect2, varscan2
- DYNC2H1 | c.9963del p.T3323Pfs*10 | Frame Shift Del (DEL) | VAF 28/246 reads (11%) | catalogued as COSV62097419; called by mutect2, varscan2
- ESR1 | c.710G>T p.C237F | Missense Mutation (SNP) | VAF 52/507 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52805147; called by muse, mutect2
- ESRRB | c.429C>A p.N143K | Missense Mutation (SNP) | VAF 63/1130 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.634); catalogued as rs370878277; called by muse, mutect2
- ESYT2 | c.2192A>T p.H731L (on ENST00000613624; = p.H655L on NM_020728.3) | Missense Mutation (SNP) | VAF 40/565 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.043); catalogued as COSV51754121; called by muse, mutect2
- FAM133A | c.308G>T p.R103L | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.018); catalogued as rs759646883, COSV100220101; called by muse, mutect2, varscan2
- FAM135B | c.1024C>A p.L342M | Missense Mutation (SNP) | VAF 26/264 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV52744841; called by muse, varscan2
- FBXL4 | c.1103G>T p.R368M | Missense Mutation (SNP) | VAF 21/194 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.533); catalogued as COSV57744878; called by muse, varscan2
- FKBP6 | c.937C>A p.R313S | Missense Mutation (SNP) | VAF 55/786 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.373); catalogued as COSV52722879; called by muse, mutect2
- FLT4 | c.2142C>A p.D714E | Missense Mutation (SNP) | VAF 51/476 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV56097982; called by muse, mutect2, varscan2
- FNDC1 | c.3733C>A p.P1245T | Missense Mutation (SNP) | VAF 71/387 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.039); catalogued as rs1226362618; called by muse, mutect2, varscan2
- GABRA1 | c.665G>T p.G222V | Missense Mutation (SNP) | VAF 46/762 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50108104; called by muse, mutect2
- HCN3 | c.1623G>A p.M541I | Missense Mutation (SNP) | VAF 19/182 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100712866; called by muse, mutect2
- HIVEP3 | c.2965C>T p.R989W | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99911550; called by muse, mutect2, varscan2
- HMCN2 | c.881C>A p.S294Y | Missense Mutation (SNP) | VAF 34/182 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV70279890; called by muse, mutect2, varscan2
- HNF4G | c.162T>A p.C54* (on ENST00000354370 / NM_001330561.2; = p.C101* on NM_004133.5) | Nonsense Mutation (SNP) | VAF 24/170 reads (14%) | catalogued as rs756011021; called by muse, mutect2, varscan2
- HUWE1 | c.11093G>T p.R3698L | Missense Mutation (SNP) | VAF 57/272 reads (21%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.931); catalogued as COSV99473633; called by muse, mutect2, varscan2
- IGHV3-43 | c.193G>T p.E65* | Nonsense Mutation (SNP) | VAF 124/553 reads (22%) | catalogued as rs1483474108; called by muse, mutect2, varscan2
- IL3RA | c.383C>A p.P128Q | Missense Mutation (SNP) | VAF 37/329 reads (11%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.801); catalogued as rs139527253; called by muse, mutect2, varscan2
- IL9R | c.50C>A p.A17D | Missense Mutation (SNP) | VAF 60/594 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1212863882; called by muse, mutect2
- KALRN | c.4615G>C p.G1539R | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53781722; called by muse, mutect2, varscan2
- KANSL1 | c.113del p.G38Afs*24 | Frame Shift Del (DEL) | VAF 26/243 reads (11%) | catalogued as COSV52265450, COSV52267120; called by mutect2, pindel, varscan2
- KCNK15 | c.832C>A p.R278S | Missense Mutation (SNP) | VAF 40/248 reads (16%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.362); catalogued as rs995969922; called by muse, mutect2, varscan2
- KIAA1549L | c.2874G>T p.K958N (on ENST00000321505; = p.K1255N on NM_012194.3) | Missense Mutation (SNP) | VAF 32/326 reads (10%) | SIFT tolerated (0.58); PolyPhen benign (0.27); catalogued as COSV55772842; called by muse, mutect2, varscan2
- KIF1A | c.1237C>A p.R413S | Missense Mutation (SNP) | VAF 42/501 reads (8%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.613); catalogued as rs374011613; called by muse, mutect2
- KRTAP19-4 | c.29G>T p.G10V | Missense Mutation (SNP) | VAF 30/322 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1163860352; called by muse, mutect2
- LGR6 | c.1137C>A p.I379= (on ENST00000367278 / NM_001017403.1; = p.I327= on NM_021636.3) | Splice Region (SNP) | VAF 24/225 reads (11%) | catalogued as COSV55158212; called by muse, mutect2, varscan2
- LGSN | c.485C>A p.A162D | Missense Mutation (SNP) | VAF 44/331 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as rs779904045; called by muse, mutect2, varscan2
- LRRTM4 | c.247G>C p.G83R | Missense Mutation (SNP) | VAF 54/681 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.329); catalogued as COSV69138812, COSV69141526; called by muse, mutect2
- MAGEC2 | c.308G>T p.C103F | Missense Mutation (SNP) | VAF 17/145 reads (12%) | SIFT tolerated (0.64); PolyPhen benign (0.433); catalogued as rs759833282; called by muse, mutect2, varscan2
- MAP1B | c.478C>T p.Q160* | Nonsense Mutation (SNP) | VAF 29/259 reads (11%) | catalogued as COSV57096779; called by muse, mutect2, varscan2
- MAST4 | c.6088C>T p.Q2030* (on ENST00000403625 / NM_001164664.2; = p.Q1841* on NM_015183.3) | Nonsense Mutation (SNP) | VAF 35/353 reads (10%) | catalogued as rs758461114; called by muse, mutect2, varscan2
- MBD1 | c.1645G>T p.E549* (on ENST00000269468 / NM_001323950.1; = p.E447* on NM_002384.2) | Nonsense Mutation (SNP) | VAF 64/840 reads (8%) | catalogued as COSV53997625; called by muse, mutect2
- MKRN3 | c.413C>A p.S138Y | Missense Mutation (SNP) | VAF 30/598 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as COSV100091900; called by muse, mutect2
- MMEL1 | c.1273-1G>C p.X425_splice | Splice Site (SNP) | VAF 41/370 reads (11%) | catalogued as COSV56525501; called by muse, mutect2, varscan2
- MS4A2 | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 42/396 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.036); catalogued as COSV54013215; called by muse, varscan2
- MUC16 | c.33947C>A p.P11316Q | Missense Mutation (SNP) | VAF 33/240 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.775); catalogued as COSV67450085; called by muse, mutect2, varscan2
- MUC7 | c.893C>T p.P298L | Missense Mutation (SNP) | VAF 76/669 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.21); catalogued as rs764564422, COSV59218662; called by muse, mutect2, varscan2
- MYH7 | c.4868A>G p.N1623S | Missense Mutation (SNP) | VAF 88/1100 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.881); catalogued as rs1306407579; ClinVar: uncertain significance; called by muse, mutect2
- NAV3 | c.3878C>A p.S1293Y | Missense Mutation (SNP) | VAF 155/842 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99886611, COSV99891195; called by muse, mutect2, varscan2
- NKAPL | c.700C>A p.H234N | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as rs866117550; called by muse, mutect2, varscan2
- NLRP2 | c.1158G>T p.R386S | Missense Mutation (SNP) | VAF 80/669 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.427); catalogued as COSV99672517; called by muse, mutect2, varscan2
- NPAP1 | c.3297C>A p.C1099* | Nonsense Mutation (SNP) | VAF 38/363 reads (10%) | catalogued as COSV100275209; called by muse, mutect2, varscan2
- OCM2 | c.101C>A p.S34* | Nonsense Mutation (SNP) | VAF 27/319 reads (8%) | catalogued as COSV57535311; called by muse, mutect2
- OR2A14 | c.35C>A p.T12N | Missense Mutation (SNP) | VAF 30/178 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.089); catalogued as rs773746634; called by muse, varscan2
- OR2B6 | c.804G>T p.K268N | Missense Mutation (SNP) | VAF 32/363 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); catalogued as COSV99773576; called by muse, mutect2
- OR4S2 | c.295C>A p.L99M | Missense Mutation (SNP) | VAF 22/256 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.776); catalogued as rs139890984, COSV56746246; called by muse, mutect2
- OR52K2 | c.634G>T p.D212Y | Missense Mutation (SNP) | VAF 26/302 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100355654; called by muse, mutect2
- OR5M11 | c.463G>T p.G155* | Nonsense Mutation (SNP) | VAF 22/298 reads (7%) | catalogued as COSV73141678; called by muse, mutect2
- OR8U1 | c.346G>T p.A116S | Missense Mutation (SNP) | VAF 48/520 reads (9%) | SIFT tolerated (0.55); PolyPhen benign (0.437); catalogued as COSV100163833; called by muse, mutect2
- PARP1 | c.2125G>T p.A709S | Missense Mutation (SNP) | VAF 68/719 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758506201, COSV64690950; called by muse, mutect2
- PHLDB1 | c.420G>A p.W140* | Nonsense Mutation (SNP) | VAF 26/198 reads (13%) | catalogued as COSV61882408; called by muse, mutect2
- PLEKHH3 | c.497G>T p.W166L | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as rs1339890857; called by muse, mutect2, varscan2
- PSD2 | c.479C>T p.S160F | Missense Mutation (SNP) | VAF 24/242 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1373394717; called by muse, mutect2, varscan2
- QPCT | c.620G>T p.W207L | Missense Mutation (SNP) | VAF 30/376 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1558606849; called by muse, mutect2
- RAMP1 | c.331G>A p.V111M | Missense Mutation (SNP) | VAF 54/904 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.115); catalogued as rs145088404, COSV99614480; called by muse, mutect2
- RBFOX1 | c.163C>G p.Q55E | Missense Mutation (SNP) | VAF 30/404 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.515); catalogued as rs1567632409; ClinVar: uncertain significance; called by muse, mutect2
- RGPD1 | c.4054G>A p.D1352N (on ENST00000409776; = p.D1360N on NM_001024457.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 88/996 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs545935139; called by muse, mutect2, varscan2
- RIMS2 | c.800C>A p.P267H (on ENST00000666250 / NM_001348490.2; = p.P75H on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 88/450 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV51691625; called by muse, mutect2, varscan2
- RND3 | c.348+1G>T p.X116_splice | Splice Site (SNP) | VAF 18/280 reads (6%) | catalogued as COSV99811897; called by muse, mutect2
- RREB1 | c.4315C>T p.P1439S | Missense Mutation (SNP) | VAF 42/322 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.018); catalogued as rs1397215816; called by muse, mutect2, varscan2
- RYR2 | c.227G>T p.R76L | Missense Mutation (SNP) | VAF 40/568 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.302); catalogued as COSV100768865; called by muse, mutect2
- RYR2 | c.639C>G p.S213R | Missense Mutation (SNP) | VAF 42/381 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.687); catalogued as COSV63717975; called by muse, mutect2, varscan2
- SCN2A | c.367A>G p.I123V | Missense Mutation (SNP) | VAF 27/371 reads (7%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.739); catalogued as rs1396703741; ClinVar: uncertain significance; called by muse, mutect2
- SHISAL2B | c.229G>T p.V77F | Missense Mutation (SNP) | VAF 21/215 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs574012886, COSV66620120; called by muse, mutect2, varscan2
- SHOX2 | c.846C>A p.F282L (on ENST00000441443 / NM_006884.3; = p.F306L on NM_003030.4) | Missense Mutation (SNP) | VAF 119/625 reads (19%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.869); catalogued as COSV67464257; called by muse, mutect2, varscan2
- SIGLEC14 | c.437C>A p.P146H | Missense Mutation (SNP) | VAF 18/290 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1257614111; called by muse, mutect2, varscan2
- SLC37A2 | c.1322C>T p.S441F | Missense Mutation (SNP) | VAF 50/505 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV53525585; called by muse, mutect2
- SLC43A1 | c.1388G>T p.C463F | Missense Mutation (SNP) | VAF 36/440 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as rs761325929; called by muse, mutect2
- SLC6A15 | c.805C>A p.L269I | Missense Mutation (SNP) | VAF 33/168 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.768); catalogued as COSV57031396; called by muse, mutect2, varscan2
- SLC8A2 | c.2141G>A p.R714Q | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.55); PolyPhen benign (0.015); catalogued as rs1196152131, COSV52642408; called by muse, varscan2
- SLIT2 | c.446G>T p.G149V | Missense Mutation (SNP) | VAF 31/319 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99880071; called by muse, mutect2, varscan2
- SMC6 | c.3091G>T p.D1031Y | Missense Mutation (SNP) | VAF 31/407 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100705149, COSV61176849; called by muse, mutect2
- SPATA1 | c.166C>T p.R56* | Nonsense Mutation (SNP) | VAF 29/195 reads (15%) | catalogued as rs377559628, COSV99759663; called by muse, mutect2, varscan2
- SPATA5 | c.341G>A p.S114N | Missense Mutation (SNP) | VAF 55/357 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.037); catalogued as rs766925357; called by muse, mutect2, varscan2
- SPATA9 | c.548G>A p.R183K | Missense Mutation (SNP) | VAF 53/417 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs770976717; called by muse, mutect2, varscan2
- SPPL2C | c.210C>A p.C70* | Nonsense Mutation (SNP) | VAF 10/175 reads (6%) | catalogued as COSV100234165; called by muse, mutect2
- SPTA1 | c.3994C>A p.Q1332K | Missense Mutation (SNP) | VAF 69/993 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV100934063; called by muse, mutect2
- SRSF11 | c.748A>T p.R250* | Nonsense Mutation (SNP) | VAF 18/164 reads (11%) | catalogued as COSV100917845; called by muse, mutect2, varscan2
- SSU72P8 | c.464T>A p.I155N | Missense Mutation (SNP) | VAF 29/429 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782351026; called by muse, mutect2
- ST6GALNAC3 | c.37G>C p.V13L | Missense Mutation (SNP) | VAF 9/154 reads (6%) | PolyPhen benign (0); catalogued as rs1226845417; called by muse, mutect2
- STAG3 | c.694C>A p.R232S | Missense Mutation (SNP) | VAF 22/350 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57934955; called by muse, mutect2
- TAS2R3 | c.836G>T p.G279V | Missense Mutation (SNP) | VAF 31/387 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as COSV56091655; called by muse, mutect2
- TEKT4 | c.578G>T p.R193L | Missense Mutation (SNP) | VAF 29/350 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.367); catalogued as COSV54624782; called by muse, mutect2
- TRIM48 | c.205T>C p.F69L | Missense Mutation (SNP) | VAF 79/743 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs141970774; called by muse, mutect2, varscan2
- TTN | c.64603G>T p.V21535L (on ENST00000591111; = p.V14111L on NM_003319.4) | Missense Mutation (SNP) | VAF 52/742 reads (7%) | PolyPhen benign (0.006); catalogued as COSV100628371; called by muse, mutect2
- USH2A | c.9055G>T p.E3019* | Nonsense Mutation (SNP) | VAF 41/768 reads (5%) | catalogued as COSV56403616; called by muse, mutect2
- USP29 | c.2335G>T p.A779S | Missense Mutation (SNP) | VAF 28/262 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.158); catalogued as COSV54144434; called by muse, mutect2, varscan2
- VWF | c.7145C>A p.T2382N | Missense Mutation (SNP) | VAF 60/504 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as COSV54619985; called by muse, mutect2, varscan2
- WASHC1 | c.805G>A p.G269S | Missense Mutation (SNP) | VAF 150/2438 reads (6%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.734); catalogued as rs762714703; called by muse, mutect2
- WNK2 | c.3307G>C p.G1103R | Missense Mutation (SNP) | VAF 21/158 reads (13%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.902); catalogued as COSV99942154; called by muse, mutect2
- WNT4 | c.1015C>G p.R339G | Missense Mutation (SNP) | VAF 45/441 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV51604596; called by muse, mutect2, varscan2
- ZFHX4 | c.2084G>T p.G695V | Missense Mutation (SNP) | VAF 22/215 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1370321607; called by muse, mutect2, varscan2
- ZFHX4 | c.10514C>T p.S3505L | Missense Mutation (SNP) | VAF 60/443 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1224803547, COSV99029695, COSV99263117; called by muse, mutect2, varscan2
- ZNF548 | c.1359G>T p.E453D | Missense Mutation (SNP) | VAF 23/148 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.381); catalogued as COSV100278310; called by muse, mutect2, varscan2
- ZNF716 | c.356G>T p.G119V | Missense Mutation (SNP) | VAF 29/211 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV101348442; called by muse, mutect2, varscan2
- ZNF781 | c.199G>T p.G67W | Missense Mutation (SNP) | VAF 24/195 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100669206; called by muse, mutect2, varscan2
- ZSCAN23 | c.550G>T p.E184* | Nonsense Mutation (SNP) | VAF 12/140 reads (9%) | catalogued as COSV57042422; called by muse, mutect2
- ABCC9 | c.4493G>T p.R1498L | Missense Mutation (SNP) | VAF 58/632 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); called by muse, mutect2
- ABHD12 | c.781G>T p.E261* | Nonsense Mutation (SNP) | VAF 124/1017 reads (12%) | called by muse, mutect2, varscan2
- ACOT7 | c.569G>C p.G190A (on ENST00000377855 / NM_181864.3; = p.G180A on NM_007274.4) | Missense Mutation (SNP) | VAF 48/442 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.878); called by mutect2, varscan2
- ADCY8 | c.2345A>G p.Y782C | Missense Mutation (SNP) | VAF 113/864 reads (13%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.693); called by muse, mutect2, varscan2
- ADGB | c.183G>C p.W61C | Missense Mutation (SNP) | VAF 25/234 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADGRD2 | c.341G>T p.R114L | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ADGRL3 | c.3551G>T p.G1184V (on ENST00000506720 / NM_001322402.2; = p.G1116V on NM_015236.6) | Missense Mutation (SNP) | VAF 28/251 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AHNAK2 | c.11633A>T p.E3878V | Missense Mutation (SNP) | VAF 95/984 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.45); called by muse, mutect2
- AKAP8 | c.1211A>C p.E404A | Missense Mutation (SNP) | VAF 34/531 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); called by muse, mutect2
- AKR1B10 | c.640G>T p.G214C | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by mutect2, varscan2
- AKR1B15 | c.724G>T p.G242C | Missense Mutation (SNP) | VAF 24/583 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- ALG13 | c.1820del p.G607Efs*59 | Frame Shift Del (DEL) | VAF 49/299 reads (16%) | called by mutect2, pindel, varscan2
- ALPK3 | c.141C>T p.T47= | Splice Region (SNP) | VAF 32/238 reads (13%) | called by muse, mutect2, varscan2
- ALX4 | c.971C>G p.P324R | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- AMPH | c.85G>T p.G29W | Missense Mutation (SNP) | VAF 46/454 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ANK2 | c.5845C>A p.Q1949K | Missense Mutation (SNP) | VAF 44/379 reads (12%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANK2 | c.8438C>G p.A2813G | Missense Mutation (SNP) | VAF 74/623 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- ANKRD30BL | c.43C>A p.P15T | Missense Mutation (SNP) | VAF 59/540 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- ANKRD35 | c.2140G>T p.G714C | Missense Mutation (SNP) | VAF 53/529 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- AOC2 | c.482C>T p.P161L | Missense Mutation (SNP) | VAF 38/406 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2
- AP002748.5 | c.281G>T p.G94V | Missense Mutation (SNP) | VAF 36/390 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); called by muse, mutect2
- APBB1 | c.922G>T p.G308* | Nonsense Mutation (SNP) | VAF 42/422 reads (10%) | called by muse, mutect2, varscan2
- ARL16 | c.541G>T p.G181C | Missense Mutation (SNP) | VAF 32/232 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARMC5 | c.394G>T p.A132S | Missense Mutation (SNP) | VAF 99/799 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- ARMCX1 | c.901G>T p.D301Y | Missense Mutation (SNP) | VAF 42/171 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ASCC3 | c.709G>T p.E237* | Nonsense Mutation (SNP) | VAF 28/251 reads (11%) | called by muse, mutect2, varscan2
- ASNSD1 | c.1729G>A p.G577R | Missense Mutation (SNP) | VAF 30/479 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- ATAD2 | c.1515G>C p.W505C | Missense Mutation (SNP) | VAF 37/318 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATP6AP2 | c.834G>T p.R278S | Missense Mutation (SNP) | VAF 41/252 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- B4GAT1 | c.78G>T p.Q26H | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.867); called by muse, mutect2
- BCHE | c.1684G>T p.G562* | Nonsense Mutation (SNP) | VAF 71/431 reads (16%) | called by muse, mutect2, varscan2
- BCL11A | c.1397A>T p.E466V (on ENST00000335712 / NM_001365609.1; = p.E500V on NM_018014.4) | Missense Mutation (SNP) | VAF 32/414 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2
- BEND2 | c.2001G>T p.W667C | Missense Mutation (SNP) | VAF 25/159 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- BRDT | c.1528A>G p.M510V | Missense Mutation (SNP) | VAF 20/218 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); called by muse, mutect2
- BTN3A2 | c.794G>T p.G265V | Missense Mutation (SNP) | VAF 62/708 reads (9%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); called by muse, mutect2
- C16orf82 | c.112C>G p.L38V | Missense Mutation (SNP) | VAF 57/596 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.234); called by muse, mutect2
- C1orf87 | c.205A>G p.I69V | Missense Mutation (SNP) | VAF 89/874 reads (10%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- C3 | c.3520G>T p.D1174Y | Missense Mutation (SNP) | VAF 61/508 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- C8orf34 | c.495G>T p.R165S | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.154); called by muse, mutect2
- CALB1 | c.401C>A p.A134E | Missense Mutation (SNP) | VAF 60/301 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CARTPT | c.16G>T p.V6L | Missense Mutation (SNP) | VAF 77/726 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CATSPER1 | c.237C>G p.H79Q | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.021); called by muse, mutect2
- CCDC136 | c.2657C>G p.A886G | Missense Mutation (SNP) | VAF 61/552 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- CCDC178 | c.1371G>C p.E457D | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- CCDC73 | c.595C>T p.L199F | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CCT6A | c.1240G>T p.V414L | Missense Mutation (SNP) | VAF 18/190 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.014); called by muse, mutect2
- CD14 | c.46C>A p.H16N | Missense Mutation (SNP) | VAF 33/328 reads (10%) | SIFT tolerated (0.5); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- CD163L1 | c.3886C>A p.L1296M | Missense Mutation (SNP) | VAF 76/678 reads (11%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- CDC42EP4 | c.448G>T p.G150W | Missense Mutation (SNP) | VAF 48/327 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- CDH24 | c.712G>T p.G238W | Missense Mutation (SNP) | VAF 67/303 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDH4 | c.810G>T p.M270I | Missense Mutation (SNP) | VAF 56/646 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.005); called by muse, mutect2
- CDK5 | c.490A>G p.T164A | Missense Mutation (SNP) | VAF 18/196 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2
- CENPF | c.496G>C p.D166H | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by mutect2, varscan2
- CEP250 | c.2509G>T p.E837* | Nonsense Mutation (SNP) | VAF 22/257 reads (9%) | called by muse, mutect2
- CEP85L | c.1877A>T p.Q626L | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- CFH | c.2569A>T p.R857* | Nonsense Mutation (SNP) | VAF 45/424 reads (11%) | called by muse, mutect2, varscan2
- CHD1 | c.1939C>T p.Q647* | Nonsense Mutation (SNP) | VAF 14/176 reads (8%) | called by muse, mutect2
- CHRNB2 | c.289G>T p.E97* | Nonsense Mutation (SNP) | VAF 61/652 reads (9%) | called by muse, mutect2
- CHST1 | c.319G>T p.G107C | Missense Mutation (SNP) | VAF 37/327 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- CMTR1 | c.1183G>T p.V395F | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); called by muse, mutect2, varscan2
- COL14A1 | c.3574G>T p.V1192L | Missense Mutation (SNP) | VAF 36/818 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- COL1A1 | c.3762C>A p.N1254K | Missense Mutation (SNP) | VAF 41/579 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.165); called by muse, mutect2
- COL7A1 | c.949G>T p.E317* | Nonsense Mutation (SNP) | VAF 220/1393 reads (16%) | called by muse, mutect2, varscan2
- CPLANE2 | c.14C>T p.P5L | Missense Mutation (SNP) | VAF 30/466 reads (6%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.07); called by muse, mutect2
- CRYBG3 | c.276G>T p.Q92H | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- CSMD1 | c.9545G>T p.C3182F (on ENST00000520002; = p.C3181F on NM_033225.6) | Missense Mutation (SNP) | VAF 19/218 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CUX2 | c.2831T>A p.L944Q | Missense Mutation (SNP) | VAF 96/397 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CXCL13 | c.119C>A p.S40* | Nonsense Mutation (SNP) | VAF 20/328 reads (6%) | called by muse, mutect2
- CYBB | c.945G>T p.K315N | Missense Mutation (SNP) | VAF 73/366 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- CYFIP1 | c.1043A>T p.Q348L | Missense Mutation (SNP) | VAF 18/270 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.165); called by muse, mutect2
- CYP7A1 | c.1438G>C p.D480H | Missense Mutation (SNP) | VAF 38/282 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- DCC | c.475C>A p.L159I | Missense Mutation (SNP) | VAF 74/570 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- DECR2 | c.160C>T p.H54Y | Missense Mutation (SNP) | VAF 18/330 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.447); called by muse, mutect2
- DGKB | c.2275G>T p.D759Y | Missense Mutation (SNP) | VAF 33/355 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DLX2 | c.770G>T p.S257I | Missense Mutation (SNP) | VAF 58/444 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- DMRTB1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 72/802 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2
- DMRTB1 | c.4G>T p.A2S | Missense Mutation (SNP) | VAF 72/804 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.049); called by muse, mutect2
- DMXL1 | c.5269A>T p.S1757C | Missense Mutation (SNP) | VAF 34/385 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.421); called by muse, mutect2
- DNAH17 | c.5351A>T p.Q1784L | Missense Mutation (SNP) | VAF 13/145 reads (9%) | SIFT tolerated (1); PolyPhen probably damaging (0.946); called by muse, mutect2
- DNMBP | c.1090C>G p.L364V | Missense Mutation (SNP) | VAF 19/432 reads (4%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); called by muse, mutect2
- DOCK2 | c.2384C>A p.A795D | Missense Mutation (SNP) | VAF 17/351 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2
- DPP10 | c.1313+1G>T p.X438_splice | Splice Site (SNP) | VAF 10/166 reads (6%) | called by muse, mutect2
- DSG4 | c.2277G>T p.R759S | Missense Mutation (SNP) | VAF 22/402 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.807); called by muse, mutect2
- DST | c.6368G>T p.S2123I | Missense Mutation (SNP) | VAF 54/582 reads (9%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.081); called by muse, mutect2
- ECPAS | c.1249G>T p.V417F | Missense Mutation (SNP) | VAF 14/175 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.058); called by muse, mutect2
- EEPD1 | c.45del p.S16Rfs*19 | Frame Shift Del (DEL) | VAF 47/379 reads (12%) | called by mutect2, pindel, varscan2
- EEPD1 | c.998G>T p.W333L | Missense Mutation (SNP) | VAF 22/421 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.422); called by muse, mutect2
- EIF4G2 | c.131G>T p.G44V | Missense Mutation (SNP) | VAF 43/484 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.942); called by muse, mutect2
- EOGT | c.91G>T p.G31C | Missense Mutation (SNP) | VAF 83/706 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- ERCC3 | c.1169G>T p.C390F | Missense Mutation (SNP) | VAF 58/624 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.091); called by muse, mutect2
- ERVFRD-1 | c.1330C>A p.Q444K | Missense Mutation (SNP) | VAF 28/288 reads (10%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.479); called by muse, mutect2
- ESRRB | c.667A>G p.K223E | Missense Mutation (SNP) | VAF 160/576 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.292); called by muse, mutect2, varscan2
- FADS6 | c.412-6C>A | Splice Region (SNP) | VAF 22/498 reads (4%) | called by muse, mutect2
- FAM135B | c.1831A>T p.T611S | Missense Mutation (SNP) | VAF 55/414 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FAM217A | c.455C>G p.P152R | Missense Mutation (SNP) | VAF 46/449 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- FAM90A10P | c.1148C>G p.A383G | Missense Mutation (SNP) | VAF 120/1766 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0.319); called by muse, mutect2
- FAM91A1 | c.778G>A p.V260I | Missense Mutation (SNP) | VAF 57/261 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- FBXO2 | c.853G>T p.A285S | Missense Mutation (SNP) | VAF 59/490 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- FEZ1 | c.396C>A p.N132K | Missense Mutation (SNP) | VAF 59/439 reads (13%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- FFAR3 | c.574C>T p.L192F | Missense Mutation (SNP) | VAF 98/992 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.712); called by muse, mutect2, varscan2
- FFAR3 | c.575T>A p.L192H | Missense Mutation (SNP) | VAF 100/984 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FLRT2 | c.1611G>T p.M537I | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- FREM3 | c.1481C>G p.T494R | Missense Mutation (SNP) | VAF 37/331 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- FRYL | c.790G>A p.A264T | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.604); called by muse, mutect2
- FTMT | c.56T>A p.L19Q | Missense Mutation (SNP) | VAF 38/377 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- GABRA1 | c.664G>C p.G222R | Missense Mutation (SNP) | VAF 46/760 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- GABRA2 | c.751G>T p.G251W | Missense Mutation (SNP) | VAF 20/356 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GAK | c.964G>T p.V322L | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- GALNTL6 | c.827G>T p.G276V | Missense Mutation (SNP) | VAF 53/351 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GBA3 | c.1236dup p.V413Sfs*10 | Frame Shift Ins (INS) | VAF 59/580 reads (10%) | called by mutect2, pindel, varscan2
- GEMIN5 | c.197G>T p.R66M | Missense Mutation (SNP) | VAF 29/241 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- GFRA1 | c.825C>G p.S275R | Missense Mutation (SNP) | VAF 102/746 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- GPRIN1 | c.2644G>A p.A882T | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- GPRIN1 | c.2198G>C p.G733A | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GPRIN1 | c.556G>T p.E186* | Nonsense Mutation (SNP) | VAF 18/250 reads (7%) | called by muse, mutect2
- GREB1L | c.2038A>T p.K680* | Nonsense Mutation (SNP) | VAF 56/471 reads (12%) | called by muse, mutect2, varscan2
- GRPR | c.40G>T p.D14Y | Missense Mutation (SNP) | VAF 32/168 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- H2AC20 | c.11G>T p.R4L | Missense Mutation (SNP) | VAF 60/654 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.935); called by muse, mutect2
- H3C10 | c.232G>C p.D78H | Missense Mutation (SNP) | VAF 36/390 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.849); called by muse, mutect2
- H4C1 | c.186T>G p.F62L | Missense Mutation (SNP) | VAF 15/267 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); called by muse, mutect2
- HMCN1 | c.2795T>A p.L932H | Missense Mutation (SNP) | VAF 48/496 reads (10%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.779); called by muse, mutect2
- HNRNPH1 | c.701G>T p.G234V | Missense Mutation (SNP) | VAF 17/185 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.583); called by muse, mutect2
- HOXB5 | c.642C>A p.H214Q | Missense Mutation (SNP) | VAF 62/647 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IFI44 | c.1297A>T p.R433W | Missense Mutation (SNP) | VAF 18/195 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); called by muse, mutect2
- IFIT1B | c.905T>C p.I302T | Missense Mutation (SNP) | VAF 49/296 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.262A>T p.T88S | Missense Mutation (SNP) | VAF 38/1406 reads (3%) | SIFT tolerated (0.12); PolyPhen benign (0.051); called by muse, mutect2
- IGKV6-21 | c.327G>C p.Q109H | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.131); called by mutect2, varscan2
- IL10RA | c.1237G>T p.A413S | Missense Mutation (SNP) | VAF 28/272 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.021); called by muse, mutect2
- IL18RAP | c.1587dup p.A530Sfs*21 | Frame Shift Ins (INS) | VAF 37/287 reads (13%) | called by mutect2, pindel, varscan2
- IL9 | c.431T>A p.I144K | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.023); called by muse, varscan2
- INHBA | c.445G>C p.V149L | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT tolerated (0.93); PolyPhen benign (0.015); called by muse, mutect2
- ITGA4 | c.2365T>A p.Y789N | Missense Mutation (SNP) | VAF 24/170 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, varscan2
- JAG2 | c.3070G>T p.V1024L | Missense Mutation (SNP) | VAF 86/1046 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.539); called by muse, mutect2
- KAT8 | c.516G>T p.A172= | Splice Region (SNP) | VAF 35/275 reads (13%) | called by muse, mutect2, varscan2
- KCNC4 | c.152G>T p.R51L | Missense Mutation (SNP) | VAF 56/471 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- KIF4B | c.2676G>T p.K892N | Missense Mutation (SNP) | VAF 42/442 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); called by muse, mutect2
- KRT35 | c.658C>A p.Q220K | Missense Mutation (SNP) | VAF 22/272 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.6); called by muse, mutect2
- KRTAP15-1 | c.173C>A p.P58H | Missense Mutation (SNP) | VAF 15/265 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- KRTAP20-1 | c.29G>T p.G10V | Missense Mutation (SNP) | VAF 14/276 reads (5%) | PolyPhen possibly damaging (0.9); called by muse, mutect2
- LOXL1 | c.1285C>T p.Q429* | Nonsense Mutation (SNP) | VAF 52/447 reads (12%) | called by muse, mutect2, varscan2
- LRRC10B | c.179C>T p.P60L | Missense Mutation (SNP) | VAF 49/375 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LRRC10B | c.563A>C p.D188A | Missense Mutation (SNP) | VAF 39/366 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- LZTS1 | c.641C>T p.T214I | Missense Mutation (SNP) | VAF 49/403 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- MCEMP1 | c.95G>T p.G32V | Missense Mutation (SNP) | VAF 25/270 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); called by muse, mutect2
- MCRS1 | c.150-4A>G | Splice Region (SNP) | VAF 63/384 reads (16%) | called by muse, mutect2, varscan2
- MDN1 | c.2965-1G>C p.X989_splice | Splice Site (SNP) | VAF 40/310 reads (13%) | called by muse, mutect2, varscan2
- MFAP3L | c.467T>A p.V156E | Missense Mutation (SNP) | VAF 49/378 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- MTMR12 | c.1515_1516insCT p.R506Lfs*12 | Frame Shift Ins (INS) | VAF 28/216 reads (13%) | called by mutect2, pindel
- MTSS2 | c.1547C>A p.T516N | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); called by muse, mutect2
- MUC17 | c.1522G>A p.E508K | Missense Mutation (SNP) | VAF 24/450 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.062); called by muse, mutect2
- MUC2 | c.544T>A p.C182S | Missense Mutation (SNP) | VAF 32/698 reads (5%) | SIFT deleterious (0); called by muse, mutect2
- MUC5B | c.5489G>A p.C1830Y | Missense Mutation (SNP) | VAF 73/480 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYF5 | c.71C>A p.P24H | Missense Mutation (SNP) | VAF 80/310 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYH2 | c.2298C>A p.H766Q | Missense Mutation (SNP) | VAF 32/936 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.768); called by muse, mutect2
- MYH4 | c.1034C>A p.T345N | Missense Mutation (SNP) | VAF 17/218 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2
- MYO15A | c.1397C>A p.P466H | Missense Mutation (SNP) | VAF 23/441 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.655); called by muse, mutect2
- MYOCD | c.2405A>T p.D802V | Missense Mutation (SNP) | VAF 19/320 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2
- MYOT | c.718C>A p.Q240K | Missense Mutation (SNP) | VAF 52/556 reads (9%) | SIFT tolerated (0.57); PolyPhen benign (0.06); called by muse, mutect2
- MYRF | c.2496G>C p.Q832H (on ENST00000278836 / NM_001127392.3; = p.Q797H on NM_013279.4) | Missense Mutation (SNP) | VAF 46/386 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- NAV3 | c.3131G>T p.S1044I | Missense Mutation (SNP) | VAF 89/482 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NCAM1 | c.282C>A p.Y94* | Nonsense Mutation (SNP) | VAF 53/594 reads (9%) | called by muse, mutect2
- NCKAP1 | c.2665C>T p.Q889* | Nonsense Mutation (SNP) | VAF 26/266 reads (10%) | called by muse, mutect2
- NCKAP1L | c.1836C>G p.C612W | Missense Mutation (SNP) | VAF 39/278 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- NCMAP | c.154A>G p.K52E | Missense Mutation (SNP) | VAF 27/432 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- NECAB1 | c.581C>A p.S194Y | Missense Mutation (SNP) | VAF 38/580 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.343); called by muse, mutect2
- NEU4 | c.823G>T p.G275C (on ENST00000391969 / NM_001167602.3; = p.G287C on NM_080741.4) | Missense Mutation (SNP) | VAF 23/174 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NGEF | c.1240C>A p.Q414K | Missense Mutation (SNP) | VAF 35/323 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NIM1K | c.1293dup p.F432Ifs*23 | Frame Shift Ins (INS) | VAF 14/118 reads (12%) | called by mutect2, pindel
- NLGN4X | c.1927C>A p.P643T | Missense Mutation (SNP) | VAF 108/749 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, varscan2
- NLGN4X | c.1558A>G p.S520G | Missense Mutation (SNP) | VAF 38/546 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NPHS1 | c.2638G>T p.V880F | Missense Mutation (SNP) | VAF 47/427 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- NRIP1 | c.2957A>T p.Y986F | Missense Mutation (SNP) | VAF 16/392 reads (4%) | SIFT tolerated (0.7); PolyPhen benign (0.244); called by muse, mutect2
- NRXN1 | c.2893G>C p.V965L | Missense Mutation (SNP) | VAF 24/160 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- NRXN3 | c.547A>G p.N183D | Missense Mutation (SNP) | VAF 35/588 reads (6%) | SIFT tolerated (1); PolyPhen possibly damaging (0.543); called by muse, mutect2
- NUAK1 | c.1750G>T p.D584Y | Missense Mutation (SNP) | VAF 96/591 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- NUGGC | c.532G>T p.E178* | Nonsense Mutation (SNP) | VAF 54/567 reads (10%) | called by muse, mutect2
- OR10G9 | c.462C>A p.H154Q | Missense Mutation (SNP) | VAF 41/484 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.982); called by muse, mutect2
- OR14A2 | c.164C>A p.T55K | Missense Mutation (SNP) | VAF 24/314 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.182); called by muse, mutect2
- OR2L2 | c.318A>T p.L106F | Missense Mutation (SNP) | VAF 58/513 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- OR51I2 | c.537C>A p.C179* | Nonsense Mutation (SNP) | VAF 42/318 reads (13%) | called by muse, mutect2, varscan2
- OR52J3 | c.331G>C p.G111R | Missense Mutation (SNP) | VAF 30/327 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- OR6S1 | c.520G>T p.G174C | Missense Mutation (SNP) | VAF 64/226 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- OR6Y1 | c.370G>T p.A124S | Missense Mutation (SNP) | VAF 44/680 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); called by muse, mutect2
- OTOS | c.26T>A p.L9Q | Missense Mutation (SNP) | VAF 21/240 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.528); called by muse, mutect2
- OXCT1 | c.1360G>T p.E454* | Nonsense Mutation (SNP) | VAF 22/346 reads (6%) | called by muse, mutect2
- PAIP1 | c.995A>C p.D332A | Missense Mutation (SNP) | VAF 20/226 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); called by muse, mutect2
- PAPPA2 | c.2884C>G p.Q962E | Missense Mutation (SNP) | VAF 50/598 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.028); called by muse, mutect2
- PARD3 | c.1940G>T p.G647V | Missense Mutation (SNP) | VAF 56/360 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- PBRM1 | c.415A>T p.K139* | Nonsense Mutation (SNP) | VAF 27/211 reads (13%) | called by muse, mutect2, varscan2
- PC | c.550T>C p.S184P | Missense Mutation (SNP) | VAF 19/198 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.295); called by muse, mutect2
- PCDHA10 | c.1750G>T p.V584L | Missense Mutation (SNP) | VAF 89/845 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- PCDHA3 | c.795C>A p.N265K | Missense Mutation (SNP) | VAF 61/548 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- PCDHA3 | c.1147G>T p.G383* | Nonsense Mutation (SNP) | VAF 103/878 reads (12%) | called by muse, mutect2, varscan2
- PCDHB14 | c.502del p.Q168Kfs*29 | Frame Shift Del (DEL) | VAF 15/136 reads (11%) | called by mutect2, pindel, varscan2
- PCDHB16 | c.352C>T p.Q118* | Nonsense Mutation (SNP) | VAF 27/245 reads (11%) | called by muse, mutect2, varscan2
- PCDHGA2 | c.2089G>T p.V697L | Missense Mutation (SNP) | VAF 124/1035 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- PCDHGA3 | c.1662C>A p.D554E | Missense Mutation (SNP) | VAF 118/1220 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PCLO | c.3057A>T p.K1019N | Missense Mutation (SNP) | VAF 48/475 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.775); called by muse, mutect2
- PER1 | c.1519A>T p.T507S | Missense Mutation (SNP) | VAF 12/280 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- PHETA1 | c.371A>T p.E124V | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- PHLDB1 | c.418T>A p.W140R | Missense Mutation (SNP) | VAF 28/207 reads (14%) | SIFT tolerated (0.92); PolyPhen benign (0); called by muse, mutect2
- PIK3R3 | c.155G>T p.G52V | Missense Mutation (SNP) | VAF 20/329 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2
- PIK3R3 | c.154G>T p.G52* | Nonsense Mutation (SNP) | VAF 20/329 reads (6%) | called by muse, mutect2
- PIKFYVE | c.442-1G>T p.X148_splice | Splice Site (SNP) | VAF 43/369 reads (12%) | called by muse, mutect2, varscan2
- PIP | c.136G>T p.V46L | Missense Mutation (SNP) | VAF 27/256 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PKHD1L1 | c.6558G>T p.W2186C | Missense Mutation (SNP) | VAF 28/269 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PKN3 | c.839C>A p.T280K | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PLCB2 | c.3429G>T p.R1143S | Missense Mutation (SNP) | VAF 19/295 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.013); called by muse, mutect2
- PLEKHA5 | c.997G>T p.G333C | Missense Mutation (SNP) | VAF 33/338 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PLEKHM2 | c.1457G>T p.G486V | Missense Mutation (SNP) | VAF 76/726 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.947); called by muse, mutect2
- PLXNB1 | c.2639G>T p.G880V | Missense Mutation (SNP) | VAF 54/336 reads (16%) | SIFT tolerated (0.64); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- POLQ | c.6253G>T p.A2085S | Missense Mutation (SNP) | VAF 50/223 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- POP1 | c.642G>T p.M214I | Missense Mutation (SNP) | VAF 62/694 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2
- PPP2R1A | c.472G>C p.V158L | Missense Mutation (SNP) | VAF 29/257 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PPP4R3C | c.908T>A p.V303E | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- PRAMEF1 | c.415C>A p.P139T | Missense Mutation (SNP) | VAF 40/546 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- PRNP | c.123G>T p.Q41H | Missense Mutation (SNP) | VAF 68/705 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.033); called by muse, mutect2
- PRUNE1 | c.284A>T p.Y95F | Missense Mutation (SNP) | VAF 18/274 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.072); called by muse, mutect2
- PTPN13 | c.7451T>A p.L2484Q (on ENST00000411767 / NM_080683.3; = p.L2465Q on NM_006264.3) | Missense Mutation (SNP) | VAF 37/330 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PTPRN | c.1828G>T p.E610* | Nonsense Mutation (SNP) | VAF 75/709 reads (11%) | called by muse, mutect2, varscan2
- RALB | c.245A>G p.Y82C | Missense Mutation (SNP) | VAF 76/795 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.633); called by muse, mutect2
- RALGAPB | c.4426G>T p.E1476* | Nonsense Mutation (SNP) | VAF 63/801 reads (8%) | called by muse, mutect2
- RBAK-RBAKDN | c.494T>C p.L165P | Missense Mutation (SNP) | VAF 17/312 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.019); called by muse, mutect2
- REV3L | c.3025G>T p.E1009* | Nonsense Mutation (SNP) | VAF 12/147 reads (8%) | called by muse, mutect2
- RGS11 | c.776G>T p.G259V (on ENST00000397770 / NM_183337.3; = p.G238V on NM_003834.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/310 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0.026); called by muse, mutect2
- RGS12 | c.2746G>T p.G916W | Missense Mutation (SNP) | VAF 40/410 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- RIMS2 | c.3169G>A p.D1057N (on ENST00000666250 / NM_001348490.2; = p.D865N on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 129/517 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RPH3A | c.387G>T p.E129D (on ENST00000389385 / NM_001143854.2; = p.E125D on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 80/431 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- SEC23A | c.1363A>G p.T455A | Missense Mutation (SNP) | VAF 167/544 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- SERINC3 | c.1332G>C p.W444C | Missense Mutation (SNP) | VAF 35/434 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SERPINB5 | c.497A>T p.Y166F | Missense Mutation (SNP) | VAF 25/247 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.115); called by muse, varscan2
- SHANK2 | c.1748dup p.Q584Pfs*3 | Frame Shift Ins (INS) | VAF 47/423 reads (11%) | called by mutect2, varscan2
- SHOX | c.856C>G p.H286D | Missense Mutation (SNP) | VAF 23/284 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.5); called by muse, mutect2
- SI | c.593C>G p.P198R | Missense Mutation (SNP) | VAF 98/409 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SIAH3 | c.274C>T p.H92Y | Missense Mutation (SNP) | VAF 11/130 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.129); called by muse, mutect2
- SIRPB1 | c.625C>A p.H209N | Missense Mutation (SNP) | VAF 30/744 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2
- SIX3 | c.663G>T p.L221F | Missense Mutation (SNP) | VAF 45/300 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC12A1 | c.961del p.E321Nfs*15 | Frame Shift Del (DEL) | VAF 37/310 reads (12%) | called by mutect2, pindel, varscan2
- SLC12A9 | c.391G>T p.G131C | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- SLC17A8 | c.627G>T p.K209N | Missense Mutation (SNP) | VAF 108/601 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- SLC23A3 | c.199C>T p.H67Y | Missense Mutation (SNP) | VAF 16/213 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.332); called by muse, mutect2
- SLC24A3 | c.1555G>T p.A519S | Missense Mutation (SNP) | VAF 24/246 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLC35G2 | c.568C>A p.P190T | Missense Mutation (SNP) | VAF 118/529 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- SLC43A1 | c.1390G>T p.G464W | Missense Mutation (SNP) | VAF 36/431 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLCO5A1 | c.853G>T p.G285* | Nonsense Mutation (SNP) | VAF 52/492 reads (11%) | called by muse, mutect2
- SLFN12L | c.611T>A p.V204D (on ENST00000260908 / NM_001363830.1; = p.V222D on NM_001195790.1) | Missense Mutation (SNP) | VAF 18/292 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- SLIT1 | c.3341G>C p.S1114T | Missense Mutation (SNP) | VAF 17/154 reads (11%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLITRK2 | c.1816C>T p.P606S | Missense Mutation (SNP) | VAF 27/155 reads (17%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- SMAD1 | c.1180C>T p.Q394* | Nonsense Mutation (SNP) | VAF 69/488 reads (14%) | called by muse, mutect2, varscan2
- SOGA3 | c.2179C>T p.R727C | Missense Mutation (SNP) | VAF 32/355 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- SOGA3 | c.2178C>A p.N726K | Missense Mutation (SNP) | VAF 33/356 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- SOX8 | c.782T>C p.F261S | Missense Mutation (SNP) | VAF 32/327 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPINDOC | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 33/350 reads (9%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.249); called by muse, mutect2
- SPIRE2 | c.766G>T p.G256* | Nonsense Mutation (SNP) | VAF 65/355 reads (18%) | called by muse, mutect2, varscan2
- SRGAP1 | c.263A>G p.K88R | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT tolerated (0.83); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- SRP72 | c.1757A>G p.Y586C | Missense Mutation (SNP) | VAF 33/404 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SSTR2 | c.111C>A p.Y37* | Nonsense Mutation (SNP) | VAF 41/509 reads (8%) | called by muse, mutect2
- ST3GAL3 | c.163+8A>T | Splice Region (SNP) | VAF 70/879 reads (8%) | called by muse, mutect2
- STK26 | c.996G>T p.K332N | Missense Mutation (SNP) | VAF 26/155 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SYNDIG1L | c.388dup p.D130Gfs*5 | Frame Shift Ins (INS) | VAF 16/154 reads (10%) | called by mutect2, pindel
- SZT2 | c.4957G>T p.G1653W (on ENST00000634258 / NM_001365999.1; = p.G1596W on NM_015284.4) | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TAF9B | c.381del p.Y127* | Frame Shift Del (DEL) | VAF 22/128 reads (17%) | called by mutect2, pindel, varscan2
- TBC1D8B | c.1460G>T p.G487V | Missense Mutation (SNP) | VAF 34/182 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TBX18 | c.1023G>T p.L341F | Missense Mutation (SNP) | VAF 34/381 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.94); called by muse, mutect2
- TBX3 | c.294G>C p.E98D | Missense Mutation (SNP) | VAF 168/779 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- TBX4 | c.584G>T p.R195L | Missense Mutation (SNP) | VAF 44/1066 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- TGFBR3 | c.1665T>A p.D555E | Missense Mutation (SNP) | VAF 40/1023 reads (4%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.976); called by muse, mutect2
- THOP1 | c.1301G>T p.C434F | Missense Mutation (SNP) | VAF 30/249 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- THSD7B | c.507A>C p.E169D | Missense Mutation (SNP) | VAF 42/380 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- TLR2 | c.1153G>A p.A385T | Missense Mutation (SNP) | VAF 38/440 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.024); called by muse, mutect2
- TMEM132C | c.101G>T p.G34V | Missense Mutation (SNP) | VAF 35/165 reads (21%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM168 | c.491G>T p.G164V | Missense Mutation (SNP) | VAF 39/353 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMX1 | c.815G>T p.G272V | Missense Mutation (SNP) | VAF 124/450 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.11); called by muse, varscan2
- TNFRSF21 | c.1139G>T p.G380V | Missense Mutation (SNP) | VAF 49/624 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2
- TOPAZ1 | c.3957T>A p.F1319L | Missense Mutation (SNP) | VAF 17/234 reads (7%) | SIFT tolerated (0.81); PolyPhen benign (0.041); called by muse, mutect2
- TRGV5 | c.70G>A p.G24R | Missense Mutation (SNP) | VAF 23/189 reads (12%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- TRIM44 | c.909G>C p.M303I | Missense Mutation (SNP) | VAF 68/513 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- TRIM58 | c.1105A>G p.R369G | Missense Mutation (SNP) | VAF 25/256 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- TRIM64B | c.1169C>A p.T390N | Missense Mutation (SNP) | VAF 68/1313 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.521); called by muse, mutect2
- TSHZ2 | c.1377G>T p.E459D | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TTC12 | c.1766G>T p.C589F | Missense Mutation (SNP) | VAF 20/292 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TTN | c.53368G>A p.D17790N (on ENST00000591111; = p.D10366N on NM_003319.4) | Missense Mutation (SNP) | VAF 76/928 reads (8%) | PolyPhen benign (0.298); called by muse, mutect2
- TTN | c.31394A>G p.E10465G (on ENST00000591111; = p.E9538G on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/213 reads (6%) | PolyPhen benign (0.366); called by muse, mutect2
- TUBA1C | c.445T>A p.F149I | Missense Mutation (SNP) | VAF 22/161 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UBA6 | c.961G>T p.A321S | Missense Mutation (SNP) | VAF 18/201 reads (9%) | SIFT tolerated (0.43); PolyPhen benign (0.009); called by muse, mutect2
- UBE2J1 | c.468G>T p.M156I | Missense Mutation (SNP) | VAF 37/344 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- USH2A | c.2618G>C p.G873A | Missense Mutation (SNP) | VAF 74/842 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); called by muse, mutect2
- USH2A | c.1683C>A p.F561L | Missense Mutation (SNP) | VAF 30/440 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- USP51 | c.277A>T p.S93C | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.253); called by muse, mutect2
- VIM | c.440G>A p.G147E | Missense Mutation (SNP) | VAF 70/464 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- VNN1 | c.1233C>A p.C411* | Nonsense Mutation (SNP) | VAF 42/371 reads (11%) | called by muse, mutect2, varscan2
- XKR7 | c.501C>A p.S167R | Missense Mutation (SNP) | VAF 18/203 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.001); called by muse, mutect2
- XYLT1 | c.2446C>A p.L816M | Missense Mutation (SNP) | VAF 18/407 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- YAE1 | c.193G>T p.G65C | Missense Mutation (SNP) | VAF 15/219 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- YTHDC2 | c.1963A>G p.R655G | Missense Mutation (SNP) | VAF 28/325 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.062); called by muse, mutect2
- ZBED1 | c.2032G>T p.G678W | Missense Mutation (SNP) | VAF 42/244 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.704); called by muse, mutect2, varscan2
- ZBTB11 | c.1113G>T p.L371F | Missense Mutation (SNP) | VAF 55/299 reads (18%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZBTB49 | c.1721G>C p.R574P | Missense Mutation (SNP) | VAF 77/595 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZC3H12C | c.1174G>A p.G392S | Missense Mutation (SNP) | VAF 24/383 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF318 | c.5911A>T p.S1971C | Missense Mutation (SNP) | VAF 26/239 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.634); called by muse, mutect2, varscan2
- ZNF407 | c.1906A>T p.T636S | Missense Mutation (SNP) | VAF 10/190 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.044); called by muse, mutect2
- ZNF462 | c.2621G>T p.R874M | Missense Mutation (SNP) | VAF 41/280 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- ZNF518B | c.3117G>T p.W1039C | Missense Mutation (SNP) | VAF 34/417 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF594 | c.514A>G p.I172V | Missense Mutation (SNP) | VAF 28/238 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.009); called by mutect2, varscan2
- ZNF695 | c.1306T>A p.Y436N | Missense Mutation (SNP) | VAF 21/249 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); called by muse, mutect2
- ZNF729 | c.760C>G p.H254D | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); called by muse, mutect2
- ZP2 | c.1297G>T p.D433Y | Missense Mutation (SNP) | VAF 20/154 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- ABRA | c.453C>A p.L151= | Silent (SNP) | VAF 182/622 reads (29%) | called by muse, mutect2, varscan2
- ACSS3 | c.219C>T p.P73= | Silent (SNP) | VAF 209/1065 reads (20%) | called by muse, mutect2, varscan2
- ADCYAP1R1 | c.346C>A p.R116= | Silent (SNP) | VAF 45/399 reads (11%) | called by muse, mutect2, varscan2
- ADGRB1 | c.3657C>A p.A1219= | Silent (SNP) | VAF 33/88 reads (38%) | called by muse, mutect2, varscan2
- AGRN | c.3360G>T p.S1120= | Silent (SNP) | VAF 51/465 reads (11%) | called by muse, mutect2, varscan2
- AGXT | c.582C>T p.Y194= | Silent (SNP) | VAF 16/361 reads (4%) | called by muse, mutect2
- ALPK2 | c.2511T>C p.S837= | Silent (SNP) | VAF 12/164 reads (7%) | called by muse, mutect2
- ARGFX | c.729C>A p.S243= | Silent (SNP) | VAF 61/242 reads (25%) | called by muse, mutect2, varscan2
- ARHGEF17 | c.5454G>T p.G1818= | Silent (SNP) | VAF 28/262 reads (11%) | called by muse, mutect2, varscan2
- ASB10 | c.399G>T p.R133= (on ENST00000420175 / NM_001142459.2; = p.R118= on NM_080871.4) | Silent (SNP) | VAF 82/496 reads (17%) | called by muse, mutect2, varscan2
- ATG2A | c.861G>T p.L287= | Silent (SNP) | VAF 22/205 reads (11%) | called by muse, mutect2, varscan2
- AVPR1B | c.1093C>A p.R365= | Silent (SNP) | VAF 74/792 reads (9%) | catalogued as COSV65638903; called by muse, mutect2
- BMP7 | c.744G>T p.S248= | Silent (SNP) | VAF 46/584 reads (8%) | catalogued as rs141957513; called by muse, mutect2
- BRSK1 | c.1644C>A p.A548= | Silent (SNP) | VAF 26/265 reads (10%) | called by muse, mutect2, varscan2
- C16orf46 | c.1128C>T p.V376= | Silent (SNP) | VAF 15/100 reads (15%) | catalogued as rs1475685440; called by muse, mutect2, varscan2
- C2orf78 | c.1020G>A p.Q340= | Silent (SNP) | VAF 29/289 reads (10%) | called by muse, mutect2, varscan2
- C9orf57 | c.333G>A p.E111= (on ENST00000377024 / NM_001371610.1; = p.E89= on NM_001128618.2) | Silent (SNP) | VAF 22/268 reads (8%) | catalogued as rs1450170441; called by muse, mutect2
- CA3 | c.96G>A p.E32= | Silent (SNP) | VAF 56/588 reads (10%) | called by muse, mutect2
- CADPS | c.417C>A p.T139= | Silent (SNP) | VAF 79/491 reads (16%) | called by muse, mutect2, varscan2
- CALCR | c.126C>T p.V42= | Silent (SNP) | VAF 28/354 reads (8%) | catalogued as rs754056336, COSV64010794; called by muse, mutect2
- CALHM5 | c.327G>T p.V109= | Silent (SNP) | VAF 22/234 reads (9%) | catalogued as COSV62067603; called by muse, mutect2
- CAMTA1 | c.1338C>G p.T446= | Silent (SNP) | VAF 45/406 reads (11%) | called by muse, mutect2, varscan2
- CARS1 | c.69G>T p.G23= | Silent (SNP) | VAF 23/276 reads (8%) | called by muse, mutect2
- CCDC27 | c.78A>C p.S26= | Silent (SNP) | VAF 34/542 reads (6%) | called by muse, mutect2
- CCIN | c.1524C>A p.P508= | Silent (SNP) | VAF 50/464 reads (11%) | called by muse, mutect2, varscan2
- CD163L1 | c.4212G>A p.E1404= | Silent (SNP) | VAF 23/193 reads (12%) | called by muse, mutect2, varscan2
- CDH12 | c.966T>C p.D322= | Silent (SNP) | VAF 22/196 reads (11%) | catalogued as rs1436159787; called by muse, mutect2
- CDH20 | c.1197T>A p.P399= | Silent (SNP) | VAF 60/664 reads (9%) | called by muse, mutect2
- CDH9 | c.957C>T p.I319= | Silent (SNP) | VAF 36/455 reads (8%) | called by muse, mutect2
- CEP72 | c.1804C>T p.L602= | Silent (SNP) | VAF 22/205 reads (11%) | called by muse, varscan2
- CNTFR | c.900G>T p.T300= | Silent (SNP) | VAF 36/323 reads (11%) | called by muse, mutect2, varscan2
- CNTNAP2 | c.2634C>T p.N878= | Silent (SNP) | VAF 96/812 reads (12%) | catalogued as rs759887207, COSV62222769; ClinVar: likely benign; called by muse, mutect2, varscan2
- CNTNAP2 | c.2736C>G p.G912= | Silent (SNP) | VAF 66/459 reads (14%) | called by muse, varscan2
- COL22A1 | c.129G>T p.L43= | Silent (SNP) | VAF 24/95 reads (25%) | called by muse, varscan2
- DCAF12L1 | c.1356A>T p.A452= | Silent (SNP) | VAF 29/131 reads (22%) | catalogued as COSV64422445; called by muse, mutect2
- DDB1 | c.837G>T p.R279= | Silent (SNP) | VAF 39/574 reads (7%) | called by muse, mutect2
- DDO | c.939G>A p.V313= (on ENST00000368924 / NM_001368172.1; = p.V254= on NM_004032.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 21/195 reads (11%) | catalogued as COSV64469685; called by muse, mutect2, varscan2
- DLGAP2 | c.456G>T p.L152= | Silent (SNP) | VAF 55/485 reads (11%) | catalogued as COSV101420967; called by muse, mutect2, varscan2
- DSCAML1 | c.5808C>A p.P1936= (on ENST00000321322; = p.P1876= on NM_020693.4) | Silent (SNP) | VAF 30/328 reads (9%) | called by muse, mutect2
- EEF1A2 | c.756C>T p.D252= | Silent (SNP) | VAF 19/242 reads (8%) | catalogued as rs866116461; called by muse, mutect2
- ELP1 | c.24G>T p.R8= | Silent (SNP) | VAF 42/510 reads (8%) | called by muse, mutect2
- ERICH3 | c.1077G>T p.V359= | Silent (SNP) | VAF 20/409 reads (5%) | catalogued as COSV58613676; called by muse, mutect2
- EYA4 | c.1899C>A p.L633= (on ENST00000531901 / NM_001301013.1; = p.L627= on NM_004100.5) | Silent (SNP) | VAF 101/879 reads (11%) | called by muse, mutect2, varscan2
- F5 | c.5976G>A p.E1992= | Silent (SNP) | VAF 57/716 reads (8%) | catalogued as rs915397925; ClinVar: likely benign; called by muse, mutect2
- FAM47A | c.648C>A p.P216= | Silent (SNP) | VAF 23/150 reads (15%) | catalogued as COSV60499038; called by muse, mutect2, varscan2
- FAT2 | c.11682C>A p.G3894= | Silent (SNP) | VAF 46/520 reads (9%) | called by muse, mutect2
- FAT3 | c.5088C>T p.I1696= | Silent (SNP) | VAF 24/286 reads (8%) | catalogued as COSV53154764; called by muse, mutect2
- FPR1 | c.1008C>G p.T336= | Silent (SNP) | VAF 17/184 reads (9%) | catalogued as COSV59050961; called by muse, mutect2
- FREM3 | c.534G>A p.V178= | Silent (SNP) | VAF 73/528 reads (14%) | called by muse, mutect2, varscan2
- FSCN1 | c.261C>A p.P87= | Silent (SNP) | VAF 45/347 reads (13%) | called by muse, mutect2, varscan2
- FZD9 | c.1437G>T p.R479= | Silent (SNP) | VAF 58/392 reads (15%) | called by muse, mutect2, varscan2
- GAL3ST4 | c.705C>A p.P235= | Silent (SNP) | VAF 26/322 reads (8%) | called by muse, mutect2
- GALR1 | c.576C>A p.P192= | Silent (SNP) | VAF 55/420 reads (13%) | catalogued as COSV100232145; called by muse, mutect2, varscan2
- GBP6 | c.345C>A p.I115= | Silent (SNP) | VAF 23/217 reads (11%) | called by muse, mutect2, varscan2
- GRM3 | c.777G>T p.V259= | Silent (SNP) | VAF 97/898 reads (11%) | catalogued as COSV64467378; called by muse, mutect2, varscan2
- GSPT2 | c.1599C>T p.S533= | Silent (SNP) | VAF 46/289 reads (16%) | catalogued as rs375119529; called by muse, mutect2, varscan2
- HIVEP1 | c.1923G>C p.T641= | Silent (SNP) | VAF 30/267 reads (11%) | catalogued as COSV101044765, COSV65100735; called by muse, mutect2, varscan2
- HR | c.2349C>A p.V783= | Silent (SNP) | VAF 37/307 reads (12%) | called by muse, mutect2, varscan2
- HS1BP3 | c.429A>T p.A143= | Silent (SNP) | VAF 32/320 reads (10%) | called by muse, mutect2
- IARS1 | c.300G>T p.L100= | Silent (SNP) | VAF 18/254 reads (7%) | called by muse, mutect2
- IGHV1OR15-9 | c.96G>A p.K32= | Silent (SNP) | VAF 18/426 reads (4%) | catalogued as rs1336432005; called by muse, mutect2
- IGSF9B | c.3678G>T p.P1226= | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as COSV58064494; called by muse, mutect2, varscan2
- IRX4 | c.1257C>A p.P419= | Silent (SNP) | VAF 26/300 reads (9%) | catalogued as rs1289048840; called by muse, mutect2
- ITGAX | c.3414G>A p.K1138= | Silent (SNP) | VAF 12/287 reads (4%) | called by muse, mutect2
- KIF1A | c.2706C>G p.G902= | Silent (SNP) | VAF 24/288 reads (8%) | catalogued as rs191727100; called by muse, mutect2
- KIF26B | c.6294C>T p.I2098= | Silent (SNP) | VAF 18/173 reads (10%) | called by muse, mutect2
- LAMB1 | c.4447C>T p.L1483= | Silent (SNP) | VAF 20/654 reads (3%) | called by muse, mutect2
- LAMB4 | c.4311T>A p.R1437= | Silent (SNP) | VAF 26/292 reads (9%) | called by muse, mutect2
- LEXM | c.636C>A p.P212= | Silent (SNP) | VAF 28/409 reads (7%) | catalogued as COSV100827778; called by muse, mutect2
- LMBRD1 | c.816G>T p.T272= (on ENST00000649011; = p.T250= on NM_018368.4) | Silent (SNP) | VAF 48/562 reads (9%) | catalogued as COSV65298158; called by muse, mutect2
- LMOD1 | c.1041C>A p.I347= | Silent (SNP) | VAF 42/415 reads (10%) | catalogued as COSV66172950, COSV66173769; called by muse, mutect2, varscan2
- LRFN2 | c.600C>A p.A200= | Silent (SNP) | VAF 66/831 reads (8%) | catalogued as COSV57824848; called by muse, mutect2
- MAPK8IP2 | c.1536G>T p.T512= | Silent (SNP) | VAF 72/448 reads (16%) | catalogued as rs773508231; called by muse, mutect2, varscan2
- MBD1 | c.1644G>A p.K548= (on ENST00000269468 / NM_001323950.1; = p.K446= on NM_002384.2) | Silent (SNP) | VAF 64/848 reads (8%) | catalogued as COSV54004722; called by muse, mutect2
- MC5R | c.225G>T p.V75= | Silent (SNP) | VAF 19/352 reads (5%) | called by muse, mutect2
- MMRN1 | c.1476A>T p.L492= | Silent (SNP) | VAF 22/206 reads (11%) | called by muse, mutect2, varscan2
- MOS | c.36G>T p.R12= | Silent (SNP) | VAF 14/76 reads (18%) | catalogued as COSV100322698; called by muse, mutect2
- MPV17L | c.234G>T p.A78= | Silent (SNP) | VAF 45/352 reads (13%) | catalogued as rs780767369, COSV99806122; called by muse, mutect2, varscan2
- MRPS30 | c.516A>C p.I172= | Silent (SNP) | VAF 42/418 reads (10%) | called by muse, mutect2
- MTUS2 | c.3630C>A p.A1210= (on ENST00000612955 / NM_001366650.1; = p.A189= on NM_015233.6) | Silent (SNP) | VAF 39/339 reads (12%) | called by muse, mutect2, varscan2
- MYH8 | c.4899C>T p.N1633= | Silent (SNP) | VAF 31/464 reads (7%) | called by muse, mutect2
- NGEF | c.1101C>A p.V367= | Silent (SNP) | VAF 29/282 reads (10%) | called by muse, mutect2
- NLRP13 | c.438C>T p.D146= | Silent (SNP) | VAF 38/361 reads (11%) | catalogued as rs182130527, COSV61622417; called by muse, mutect2, varscan2
- NOS3 | c.2463G>T p.P821= | Silent (SNP) | VAF 39/205 reads (19%) | called by muse, mutect2, varscan2
- NPAS4 | c.1179C>A p.P393= | Silent (SNP) | VAF 24/245 reads (10%) | called by muse, mutect2
- NR2F2 | c.1080C>T p.F360= | Silent (SNP) | VAF 65/680 reads (10%) | catalogued as rs781196629; called by muse, mutect2
- NRXN3 | c.1146T>C p.Y382= (on ENST00000335750 / NM_001330195.2; = p.Y9= on NM_004796.6) | Silent (SNP) | VAF 44/542 reads (8%) | catalogued as rs376827828; called by muse, mutect2
- NSUN3 | c.864T>G p.P288= | Silent (SNP) | VAF 103/561 reads (18%) | called by muse, mutect2, varscan2
- NTNG1 | c.1479G>T p.T493= (on ENST00000370068 / NM_001113226.3; = p.T392= on NM_014917.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 38/350 reads (11%) | catalogued as COSV100903726; called by muse, mutect2, varscan2
- NTRK1 | c.2067G>A p.L689= | Silent (SNP) | VAF 36/517 reads (7%) | catalogued as rs1057521447; ClinVar: likely benign; called by muse, mutect2
- OLFML2A | c.1902G>C p.V634= | Silent (SNP) | VAF 47/266 reads (18%) | called by muse, mutect2, varscan2
- OSER1 | c.720G>T p.S240= | Silent (SNP) | VAF 44/299 reads (15%) | catalogued as COSV99667476; called by muse, mutect2, varscan2
- OXR1 | c.339C>A p.A113= (on ENST00000442977 / NM_001198532.1; = p.A112= on NM_018002.3) | Silent (SNP) | VAF 28/233 reads (12%) | called by muse, mutect2, varscan2
- PCDH11X | c.2248T>C p.L750= | Silent (SNP) | VAF 38/327 reads (12%) | called by muse, mutect2, varscan2
- PCDHB10 | c.466A>C p.R156= | Silent (SNP) | VAF 50/546 reads (9%) | catalogued as COSV53384854; called by muse, mutect2
- PCDHB4 | c.1614G>A p.P538= | Silent (SNP) | VAF 225/2084 reads (11%) | called by muse, varscan2
- PCDHB8 | c.1290C>G p.P430= | Silent (SNP) | VAF 136/2332 reads (6%) | called by muse, mutect2
- PCDHGA6 | c.1221T>C p.N407= | Silent (SNP) | VAF 90/896 reads (10%) | catalogued as rs1436249937; called by muse, mutect2
- PCDHGB1 | c.1635C>A p.R545= | Silent (SNP) | VAF 94/862 reads (11%) | catalogued as COSV54034813; called by muse, mutect2, varscan2
- POU3F3 | c.324C>A p.A108= | Silent (SNP) | VAF 19/155 reads (12%) | called by muse, varscan2
- PRL | c.21A>T p.P7= | Silent (SNP) | VAF 39/489 reads (8%) | called by muse, mutect2
- PSG4 | c.966C>T p.D322= | Silent (SNP) | VAF 39/209 reads (19%) | catalogued as rs750504490, COSV54935617; called by muse, mutect2, varscan2
- PTPRT | c.384T>C p.G128= | Silent (SNP) | VAF 31/252 reads (12%) | called by muse, mutect2, varscan2
- PTPRZ1 | c.6174C>A p.I2058= | Silent (SNP) | VAF 16/236 reads (7%) | called by muse, mutect2
- PXDNL | c.2340C>A p.P780= | Silent (SNP) | VAF 7/64 reads (11%) | called by mutect2, varscan2
- RBFOX1 | c.162C>A p.G54= | Silent (SNP) | VAF 30/402 reads (7%) | called by muse, mutect2
- RPS6KL1 | c.1050G>A p.E350= | Silent (SNP) | VAF 23/191 reads (12%) | called by muse, mutect2, varscan2
- RTL1 | c.3297G>T p.L1099= | Silent (SNP) | VAF 123/488 reads (25%) | called by muse, mutect2, varscan2
- RYR2 | c.228G>T p.R76= | Silent (SNP) | VAF 40/570 reads (7%) | called by muse, mutect2
- RYR2 | c.8799G>T p.V2933= | Silent (SNP) | VAF 18/228 reads (8%) | called by muse, mutect2
- SIK3 | c.3054G>A p.R1018= (on ENST00000445177 / NM_001366686.2; = p.R976= on NM_025164.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/106 reads (9%) | catalogued as COSV99408179; called by muse, mutect2, varscan2
- SLC49A3 | c.1116G>C p.V372= (on ENST00000404286 / NM_001294341.2; = p.V371= on NM_032219.4) | Silent (SNP) | VAF 38/553 reads (7%) | catalogued as rs770286414; called by muse, mutect2
- SLC4A7 | c.723T>C p.H241= | Silent (SNP) | VAF 94/522 reads (18%) | called by muse, mutect2, varscan2
- SLC5A12 | c.210C>G p.T70= | Silent (SNP) | VAF 60/574 reads (10%) | called by muse, mutect2, varscan2
- SPNS3 | c.393C>T p.I131= | Silent (SNP) | VAF 11/95 reads (12%) | called by muse, mutect2, varscan2
- SSTR1 | c.933C>A p.L311= | Silent (SNP) | VAF 76/837 reads (9%) | called by muse, mutect2
- ST6GALNAC5 | c.363C>A p.I121= | Silent (SNP) | VAF 24/493 reads (5%) | called by muse, mutect2
- ST8SIA6 | c.981C>T p.I327= | Silent (SNP) | VAF 65/614 reads (11%) | called by muse, mutect2, varscan2
- STARD3 | c.135C>T p.A45= | Silent (SNP) | VAF 93/1034 reads (9%) | called by muse, mutect2
- SYNDIG1 | c.117G>T p.L39= | Silent (SNP) | VAF 48/752 reads (6%) | called by muse, mutect2
- SYNE2 | c.18402G>A p.T6134= | Silent (SNP) | VAF 63/1032 reads (6%) | catalogued as rs374459819; called by muse, mutect2
- TG | c.3297T>C p.S1099= | Silent (SNP) | VAF 50/1110 reads (5%) | called by muse, mutect2
- TLL1 | c.1452G>A p.P484= | Silent (SNP) | VAF 70/740 reads (9%) | catalogued as rs1488853065; called by muse, mutect2
- TMC3 | c.870T>G p.A290= | Silent (SNP) | VAF 29/230 reads (13%) | called by muse, mutect2, varscan2
- TMEM132C | c.30G>T p.P10= | Silent (SNP) | VAF 9/28 reads (32%) | called by muse, mutect2, varscan2
- TMEM171 | c.237C>A p.S79= | Silent (SNP) | VAF 32/378 reads (8%) | called by muse, mutect2
- TNN | c.228G>C p.G76= | Silent (SNP) | VAF 25/276 reads (9%) | called by muse, mutect2
- TRIM26 | c.738G>C p.A246= | Silent (SNP) | VAF 45/440 reads (10%) | catalogued as COSV101359496; called by muse, mutect2, varscan2
- TRPV5 | c.1104C>T p.L368= | Silent (SNP) | VAF 80/484 reads (17%) | catalogued as rs779321635; called by mutect2, varscan2
- TTBK1 | c.3726G>T p.A1242= | Silent (SNP) | VAF 16/132 reads (12%) | called by muse, mutect2, varscan2
- TTN | c.45870C>A p.V15290= (on ENST00000591111; = p.V7866= on NM_003319.4) | Silent (SNP) | VAF 36/879 reads (4%) | called by muse, mutect2
- UPK1B | c.240C>A p.I80= | Silent (SNP) | VAF 160/646 reads (25%) | called by muse, mutect2, varscan2
- UQCRHL | c.105G>A p.E35= | Silent (SNP) | VAF 58/694 reads (8%) | catalogued as rs777650955; called by muse, mutect2
- USH2A | c.8445C>A p.T2815= | Silent (SNP) | VAF 29/263 reads (11%) | catalogued as rs373677094; called by muse, mutect2, varscan2
- USH2A | c.7881C>A p.I2627= | Silent (SNP) | VAF 52/688 reads (8%) | catalogued as COSV56378138; called by muse, mutect2
- USH2A | c.3591C>A p.S1197= | Silent (SNP) | VAF 47/681 reads (7%) | catalogued as COSV56324693, COSV56433204; called by muse, mutect2
- VPS13A | c.705G>A p.L235= | Silent (SNP) | VAF 19/252 reads (8%) | called by muse, mutect2
- VPS13B | c.2640C>T p.A880= | Silent (SNP) | VAF 241/986 reads (24%) | catalogued as rs768556981; called by muse, mutect2, varscan2
- WSCD2 | c.816G>T p.L272= | Silent (SNP) | VAF 44/156 reads (28%) | called by muse, varscan2
- ZNF142 | c.693C>T p.P231= | Silent (SNP) | VAF 36/289 reads (12%) | catalogued as rs1396559931; called by muse, mutect2, varscan2
- ZSCAN1 | c.669G>T p.G223= | Silent (SNP) | VAF 31/231 reads (13%) | called by muse, mutect2, varscan2
- AC004890.2 | n.1599+81G>T | Intron (SNP) | VAF 23/169 reads (14%) | called by muse, mutect2, varscan2
- AC012485.1 | n.288G>C | RNA (SNP) | VAF 43/1051 reads (4%) | called by muse, mutect2
- AC068473.1 | n.526C>A | RNA (SNP) | VAF 45/406 reads (11%) | called by muse, mutect2, varscan2
- AC092675.1 | n.459-166A>T | Intron (SNP) | VAF 38/392 reads (10%) | called by muse, mutect2
- AC114490.3 | c.*849G>T | 3'UTR (SNP) | VAF 58/738 reads (8%) | catalogued as rs1179937084; called by muse, mutect2
- AC133561.1 | n.1955C>A | RNA (SNP) | VAF 61/344 reads (18%) | called by muse, mutect2, varscan2
- ADAM6 | n.1351T>A | RNA (SNP) | VAF 68/586 reads (12%) | called by muse, mutect2, varscan2
- ADAM9 | c.*1503A>G | 3'UTR (SNP) | VAF 10/161 reads (6%) | called by muse, mutect2
- AKR1B1P6 | n.231C>A | RNA (SNP) | VAF 24/260 reads (9%) | called by muse, mutect2
- AL353804.7 | chrX:73849542 G>A | 5'Flank (SNP) | VAF 108/593 reads (18%) | catalogued as rs751231794; called by muse, mutect2, varscan2
- AOPEP | c.*5-1394G>T | Intron (SNP) | VAF 46/325 reads (14%) | catalogued as rs752742190; called by muse, mutect2, varscan2
- ATOH8 | c.960+8623G>C | Intron (SNP) | VAF 71/705 reads (10%) | called by muse, mutect2
- BRD8 | c.117-614G>T | Intron (SNP) | VAF 24/156 reads (15%) | catalogued as rs1325204122; called by muse, mutect2, varscan2
- BTBD11 | c.2991+24G>T | Intron (SNP) | VAF 57/192 reads (30%) | called by muse, mutect2, varscan2
- CD8A | c.-67del | 5'UTR (DEL) | VAF 44/406 reads (11%) | called by mutect2, varscan2
- CFL2 | c.*1661G>T | 3'UTR (SNP) | VAF 301/888 reads (34%) | called by muse, mutect2, varscan2
- CHCHD2 | c.-57C>A | 5'UTR (SNP) | VAF 30/367 reads (8%) | catalogued as rs1236532162, COSV101271049; called by muse, mutect2
- COPS3 | c.55+528G>T | Intron (SNP) | VAF 18/230 reads (8%) | called by muse, mutect2
- CR1 | c.487+12294C>A | Intron (SNP) | VAF 44/892 reads (5%) | catalogued as COSV100888100; called by muse, mutect2
- CST7 | c.-10C>A | 5'UTR (SNP) | VAF 30/462 reads (6%) | catalogued as COSV100961935; called by muse, mutect2
- CTBP2 | c.58+12009G>C | Intron (SNP) | VAF 74/455 reads (16%) | catalogued as rs755005239, COSV58339721; called by muse, mutect2, varscan2
- DAO | c.696-19C>A | Intron (SNP) | VAF 64/434 reads (15%) | called by muse, mutect2, varscan2
- ESRP2 | c.710+11G>C | Intron (SNP) | VAF 69/610 reads (11%) | called by muse, mutect2, varscan2
- FAM90A27P | n.222C>A | RNA (SNP) | VAF 19/283 reads (7%) | called by muse, mutect2
- FBXW7 | c.501+29114G>T | Intron (SNP) | VAF 23/161 reads (14%) | catalogued as rs1409665473; called by muse, mutect2, varscan2
- FDXR | c.79+38G>T | Intron (SNP) | VAF 40/310 reads (13%) | called by muse, mutect2, varscan2
- FGG | c.-16C>A | 5'UTR (SNP) | VAF 44/522 reads (8%) | called by muse, mutect2
- FHL2 | chr2:105399249 G>T | 5'Flank (SNP) | VAF 30/370 reads (8%) | called by muse, mutect2
- FRMD3 | c.596+3611C>A | Intron (SNP) | VAF 26/222 reads (12%) | called by muse, mutect2, varscan2
- GTF2IRD2P1 | n.1101C>G | RNA (SNP) | VAF 51/401 reads (13%) | called by muse, mutect2, varscan2
- HERC2P4 | n.477C>A | RNA (SNP) | VAF 54/455 reads (12%) | called by muse, mutect2, varscan2
- HFM1 | c.-34C>G | 5'UTR (SNP) | VAF 44/413 reads (11%) | called by muse, mutect2
- HSP90B3P | n.793G>T | RNA (SNP) | VAF 33/399 reads (8%) | called by muse, mutect2
- IGFN1 | c.1242-2131G>T | Intron (SNP) | VAF 20/617 reads (3%) | called by muse, mutect2
- IQCE | c.131-59T>A | Intron (SNP) | VAF 26/379 reads (7%) | called by muse, mutect2
- ITGA6 | c.307+34G>T | Intron (SNP) | VAF 64/674 reads (9%) | called by muse, mutect2
- KLHL9 | c.*8G>T | 3'UTR (SNP) | VAF 33/397 reads (8%) | catalogued as rs749001440; called by muse, mutect2
- LIG3 | c.-102G>T | 5'UTR (SNP) | VAF 16/269 reads (6%) | called by muse, mutect2
- LINC02453 | n.113T>A | RNA (SNP) | VAF 20/134 reads (15%) | called by muse, mutect2, varscan2
- LOXHD1 | c.5517+41C>G | Intron (SNP) | VAF 16/280 reads (6%) | called by muse, mutect2
- MAP7 | c.68-45021G>A | Intron (SNP) | VAF 13/129 reads (10%) | called by muse, mutect2, varscan2
- MDM1 | c.134-422C>T | Intron (SNP) | VAF 52/333 reads (16%) | catalogued as rs1046444236; called by muse, mutect2, varscan2
- MFRP | chr11:119343918 A>T | 5'Flank (SNP) | VAF 104/1118 reads (9%) | called by muse, mutect2
- MFSD4B | c.*115A>G | 3'UTR (SNP) | VAF 22/302 reads (7%) | called by muse, mutect2
- MIR1269A | n.97G>T | RNA (SNP) | VAF 22/267 reads (8%) | called by muse, mutect2
- MIR496 | n.21G>A | RNA (SNP) | VAF 80/413 reads (19%) | catalogued as rs1400598914; called by muse, mutect2, varscan2
- MTRNR2L6 | chr7:142671208 C>T | 3'Flank (SNP) | VAF 19/161 reads (12%) | called by muse, mutect2, varscan2
- MUC2 | chr11:1099504 C>A | 5'Flank (SNP) | VAF 82/1730 reads (5%) | called by muse, mutect2
- NANOS3 | chr19:13874955 A>T | 5'Flank (SNP) | VAF 5/35 reads (14%) | called by mutect2, varscan2
- NDUFA13 | c.*14C>T | 3'UTR (SNP) | VAF 44/539 reads (8%) | catalogued as rs747596537; called by muse, mutect2
- NTM-AS1 | n.2445C>T | RNA (SNP) | VAF 10/74 reads (14%) | catalogued as rs1388026973; called by muse, varscan2
- OBP2A | c.389-59C>A | Intron (SNP) | VAF 19/79 reads (24%) | called by muse, varscan2
- OBSCN | c.988+25C>A | Intron (SNP) | VAF 16/243 reads (7%) | catalogued as COSV52782251; called by muse, mutect2
- OR9Q1 | c.-15+53351G>A | Intron (SNP) | VAF 57/481 reads (12%) | catalogued as rs775156419, COSV59049694; called by muse, mutect2, varscan2
- ORC6 | c.*328G>T | 3'UTR (SNP) | VAF 24/174 reads (14%) | called by muse, mutect2, varscan2
- PDE1C | c.1892-14480G>A | Intron (SNP) | VAF 19/247 reads (8%) | called by muse, mutect2
- PEG10 | c.*391C>A | 3'UTR (SNP) | VAF 74/615 reads (12%) | called by muse, mutect2, varscan2
- PITX2 | c.390+149G>T | Intron (SNP) | VAF 40/353 reads (11%) | catalogued as rs759041748, COSV60740091; called by muse, mutect2, varscan2
- PKD1L2 | n.1369C>T | RNA (SNP) | VAF 35/212 reads (17%) | catalogued as rs564602999; called by muse, mutect2
- PTPRR | c.1498-10287C>A | Intron (SNP) | VAF 63/389 reads (16%) | called by muse, mutect2, varscan2
- RARS2 | c.111-378T>A | Intron (SNP) | VAF 8/89 reads (9%) | called by muse, mutect2
- RGSL1 | c.302-1019G>T | Intron (SNP) | VAF 28/269 reads (10%) | called by muse, mutect2
- RN7SL495P | chr15:22608289 C>T | 3'Flank (SNP) | VAF 46/426 reads (11%) | called by mutect2, varscan2
- RNA5-8SP2 | chr16:34159856 G>T | 5'Flank (SNP) | VAF 29/198 reads (15%) | called by muse, mutect2, varscan2
- RNF121 | chr11:71929022 G>T | 5'Flank (SNP) | VAF 33/337 reads (10%) | called by muse, mutect2, varscan2
- RNU6-389P | chr7:55685285 C>A | 5'Flank (SNP) | VAF 16/306 reads (5%) | called by muse, mutect2
- SCIN | c.199+608G>T | Intron (SNP) | VAF 37/328 reads (11%) | catalogued as rs749366061; called by muse, mutect2, varscan2
- SCN9A | c.596+27G>T | Intron (SNP) | VAF 37/363 reads (10%) | called by muse, mutect2, varscan2
- SHISA9 | c.563+5943T>C | Intron (SNP) | VAF 22/398 reads (6%) | catalogued as rs1389627433; called by muse, mutect2
- SLC13A4 | c.1220+36C>A | Intron (SNP) | VAF 16/266 reads (6%) | catalogued as COSV100818889; called by muse, mutect2
- SLC25A37 | c.*1922G>T | 3'UTR (SNP) | VAF 17/118 reads (14%) | called by muse, mutect2, varscan2
- SLC5A5 | c.*17G>T | 3'UTR (SNP) | VAF 28/273 reads (10%) | called by muse, mutect2
- SPATA31C2 | n.750C>A | RNA (SNP) | VAF 64/926 reads (7%) | called by muse, mutect2
- SPTA1 | c.7134+37C>A | Intron (SNP) | VAF 32/492 reads (7%) | called by muse, mutect2
- TDP1 | c.1753+98G>T | Intron (SNP) | VAF 126/466 reads (27%) | called by muse, mutect2, varscan2
- TF | c.635+23C>T | Intron (SNP) | VAF 68/411 reads (17%) | catalogued as rs759543917; called by muse, mutect2, varscan2
- TMA7 | c.-6G>T | 5'UTR (SNP) | VAF 15/90 reads (17%) | called by muse, varscan2
- TMEM135 | c.*3515A>G | 3'UTR (SNP) | VAF 19/133 reads (14%) | called by muse, mutect2, varscan2
- TPD52L2 | c.*30A>T | 3'UTR (SNP) | VAF 38/448 reads (8%) | called by muse, mutect2
- TRO | c.*81C>T | 3'UTR (SNP) | VAF 26/188 reads (14%) | catalogued as COSV51497881; called by muse, mutect2, varscan2
- UMOD | c.89-633G>T | Intron (SNP) | VAF 23/252 reads (9%) | catalogued as COSV56779076; called by muse, mutect2
- USP38 | c.1209+922del | Intron (DEL) | VAF 12/104 reads (12%) | called by mutect2, varscan2
- UTP25 | c.-31C>T | 5'UTR (SNP) | VAF 20/350 reads (6%) | catalogued as COSV101530970, COSV101530971; called by muse, mutect2
- VAPB | c.*2808G>T | 3'UTR (SNP) | VAF 24/203 reads (12%) | called by muse, mutect2, varscan2
- VPS51 | chr11:65096209 C>T | 5'Flank (SNP) | VAF 28/385 reads (7%) | called by muse, mutect2
- WWP2 | c.1683-863G>A | Intron (SNP) | VAF 75/523 reads (14%) | called by muse, mutect2, varscan2
- Z82190.2 | c.1787-21902T>A | Intron (SNP) | VAF 22/275 reads (8%) | called by muse, mutect2
- ZEB2 | c.73+5075C>A | Intron (SNP) | VAF 31/290 reads (11%) | called by muse, mutect2, varscan2
- ZMYND8 | c.26-8504_26-8499del | Intron (DEL) | VAF 25/265 reads (9%) | called by mutect2, pindel
- ZNF783 | c.802+3644G>T | Intron (SNP) | VAF 43/472 reads (9%) | called by muse, mutect2
